Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042795-09A.1 (aliquot TARGET-15-SJMPAL042795-09A.1-01D) from TARGET case TARGET-15-SJMPAL042795, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.5 years (200 days).
Specimen TARGET-15-SJMPAL042795-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66bb35cb-a496-43c7-ae6c-8ce4202136c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042795-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042795-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa3d71a9-9424-46a5-94a6-88077327dd57

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMKK1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as rs113610926, COSV50126685; called by muse, mutect2, varscan2
- PIK3CD | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV63128987; called by muse, mutect2, varscan2
- ABCC1 | c.2481C>A p.H827Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- H1-8 | c.680C>A p.A227E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- PPM1F | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.59); called by muse, mutect2
- PXDC1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TP53 | c.848_851del p.R283Qfs*61 | Frame Shift Del (DEL) | VAF 26/168 reads (15%) | called by pindel*, varscan2
- APP | c.711G>A p.V237= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as rs770301922; called by muse, varscan2
- KCNQ4 | c.1704C>A p.G568= | Silent (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- MUC4 | c.9453C>G p.T3151= | Silent (SNP) | VAF 18/361 reads (5%) | catalogued as rs762872827; called by muse, mutect2
- RGPD4 | c.3345G>A p.T1115= | Silent (SNP) | VAF 63/97 reads (65%) | catalogued as rs1170361941; called by muse, mutect2, varscan2
- TUBB8 | c.21G>A p.T7= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs1228342230, COSV59116768; called by muse, mutect2, varscan2
